Surgical pathology report (de-identified scan), TCGA case TCGA-CN-A49C, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-CN-A49C-01A (Primary Tumor).

[page 1 of 3]
Pathology Report

CORRECTED

Report Type Pathology Report
Date of Event
Sex M
Authored by
Hosp/Group
Record Status CORRECTED

COMPREHENSIVE THERANOSTIC SUMMARY

IMMUNOHISTOCHEMISTRY:
p16:

RESULTS
POSITIVE

IN SITU HYBRIDIZATION / FISH:
HPV:
subtypes PAN
selective probe set
Punctate

RESULTS
POSITIVE;

Pattern:

**See Special Procedure reports below for additional details and background on
In situ/FISH and/or Molecular Anatomic Pathology testing as
pertinent**

ICD-O-3
carcinoma, squamous cell
non-keratinizing, NOS 8072/3
Site: tonsil, NOS C09.9

Pathologist:
** Report Electronically Signed Out **
By Pathologist:

Site: tonsil, NOS C09.9

4/29/12

My signature is attestation that I have personally reviewed the
submitted
material(s) and the above diagnosis reflects that evaluation.

FINAL DIAGNOSIS:
TONSIL, RIGHT, BIOPSY
INVASIVE SQUAMOUS CELL CARCINOMA, NON-KERATINIZING TYPE (see comment).

COMMENT:
A p16 immunostain and in-situ hybridization for human papilloma virus
(HPV)
DNA will be performed and reported as an addendum.

Pathologist:
** Report Electronically Signed Out **
By Pathologist:

My signature is attestation that I have personally reviewed the
submitted
material(s) and the final diagnosis reflects that evaluation.

IHPAA Discrepancy		

8/20/12

[page 2 of 3]
GROSS DESCRIPTION:

The specimen is received unfixed labeled with the patient's name, initials XXX and "biopsy of right tonsil". The specimen consists of multiple tan-gray, soft to firm fragments of tissue measuring 1.5 x 1.0 x 0.3 cm in aggregate. Following frozen section consult the specimens are entirely submitted in cassette labeled AFS. Formalin exposure time: 33 hours
GROSSED BY:

INTRAOPERATIVE CONSULTATION:

- 1 AFS: BIOPSY OF RIGHT TONSIL (frozen section)-
A. SUFFICIENT FOR ANCILLARY STUDIES.
B. MALIGNANT.
C. SQUAMOUS CELL CARCINOMA

MICROSCOPIC:

Microscopic examination substantiates the above diagnosis.

The following statement applies to all immunohistochemistry, Insitu Hybridization Assays (ISH & FISH), Molecular Anatomic Pathology, and Immunofluorescent Testing:

The testing was developed and its performance characteristics determined by

the Department of Pathology, as required by the CLIA

'88 regulations. The testing has not been cleared or approved for the specific use by the U.S. Food and Drug Administration, but the FDA has determined such approval is not necessary for clinical use. Tissue fixation

ranges from a minimum of 2 to a maximum of 84 hours.

This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 ("CLIA") as qualified to perform high-complexity clinical

testing. Pursuant to the requirements of CLIA, ASR's used in this laboratory

have been established and verified for accuracy and precision.

Additional

information about this type of test is available upon request.

PATIENT HISTORY:

CHIEF COMPLAINT/PRE-OP/POST-OP DIAGNOSIS: Tonsil mass

PROCEDURE: Direct laryngoscopy and biopsy

SPECIFIC CLINICAL QUESTION: Not answered

OUTSIDE TISSUE DIAGNOSIS: Not answered

PRIOR MALIGNANCY: Not answered

CHEMOTHERAPY: Not answered

ORGAN TRANSPLANT: Not answered

IMMUNOSUPPRESSION: Not answered

OTHER DISEASES: Not answered

HISTO TISSUE SUMMARY/SLIDES REVIEWED:

Part 1: Biopsy of Right Tonsil

Taken:

Stain/ Block

[page 3 of 3]
ANEG Mouse x 1 AFS
HHE x 1 AFS
HCOM x 1 AFS
ISHBNK x 1 AFS
ISHBNK x 1 AFS
H&E x 1 AFS
HPV x 1 AFS
IISH x 1 AFS
P16 x 1 AFS
TC1

Source: NCI Genomic Data Commons file 445d5852-f475-40ed-9048-dbeb9a6207ca (TCGA-CN-A49C.D63CFB90-036A-45D7-B27C-AA306B034673.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).